CPTAC case C3L-02212 — Kidney — Transitional Cell Papillomas and Carcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/773b2752-d7ba-4dfd-bc74-b979053c6b76

Demographics
Sex at birth: male; Race: white; Year of birth: 1946; Vital status: Dead; Days to death: 1,429 days (3.9 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Urothelial carcinoma, NOS: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 70.5 years (25,745 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,429 days (3.9 years); Days to last follow up: 1,429 days (3.9 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 427 days (1.2 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 749 days (2.1 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 750 days (2.1 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 224 days; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,116 days (3.1 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 0.

Other clinical attributes
- Weight: 97.98 kg; Height: 185.42 cm; BMI: 28.49.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02212-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 34 days; Initial weight: 200 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02212-21: Section location: Middle; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3L-02212-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 34 days; Initial weight: 150 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02212-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 34 days; Method of sample procurement: Blood Draw.
